Somatic mutation profile of cancer-model specimen HCM-CSHL-0726-C18-85M (3D Organoid, passage 5; aliquot HCM-CSHL-0726-C18-85M-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0726-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.5 years (22,840 days).
Specimen HCM-CSHL-0726-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2450d753-1f36-47a4-a282-a350d4ceeaca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0726-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0726-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea6a791e-2e3d-4072-b104-acd17439c88c

The open-access MAF lists 161 somatic variants for this specimen: 115 protein-altering or splice-affecting, 41 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 41, Nonsense Mutation 11, Frame Shift Ins 6, Frame Shift Del 5, Intron 4, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 257/524 reads (49%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 196/420 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PANK2 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 260/263 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852961, CM014233; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 167/355 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 242/242 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- ABCB9 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 327/688 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1240661251; called by muse, mutect2, varscan2
- ADAMTS4 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 605/902 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs148469372, COSV63489474; called by muse, varscan2
- ADCY8 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 279/564 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs781717717, COSV53895224, COSV53899162; called by muse, mutect2, varscan2
- ARMH4 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 169/343 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs142845597; called by muse, mutect2, varscan2
- ATAD2 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 175/435 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs1384549068, COSV54883488; called by muse, mutect2, varscan2
- BCAS3 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 142/296 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as rs751009642, COSV66774059; called by muse, mutect2, varscan2
- BRD2 | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 163/322 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.835); catalogued as rs982026329, COSV100875594; called by muse, varscan2
- CCDC157 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 166/364 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147104395; called by muse, mutect2
- CCDC178 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 100/100 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV55760343; called by muse, varscan2
- CCDC28A | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 229/481 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs207467466, COSV60425668; called by muse, mutect2, varscan2
- CDH11 | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 114/230 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as rs1471732983, COSV51758237, COSV51771976; called by muse, varscan2
- CSNK1A1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 167/338 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV55792565; called by muse, mutect2, varscan2
- DENND2D | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 229/452 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs557909053; called by muse, varscan2
- DNAH14 | c.6742C>T p.R2248* (on ENST00000445597; = p.R2901* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 340/559 reads (61%) | catalogued as rs1034955641; called by muse, mutect2, varscan2
- DOP1B | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 300/640 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs771546721; called by muse, mutect2, varscan2
- DPF2 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 222/494 reads (45%) | catalogued as COSV52891512; called by muse, varscan2
- DSCAML1 | c.3526C>T p.R1176C (on ENST00000321322; = p.R1116C on NM_020693.4) | Missense Mutation (SNP) | VAF 334/726 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261758140, COSV100356200, COSV58390029; called by muse, mutect2, varscan2
- FAM47B | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 310/634 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs780975161, COSV61454531; called by muse, varscan2
- HIP1 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 182/445 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs781989848, COSV61183052; called by muse, mutect2, varscan2
- ITPK1 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 247/567 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs916309062, COSV99968165; called by muse, mutect2, varscan2
- KCNF1 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 860/860 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54464918; called by muse, varscan2
- KCNJ6 | c.619A>G p.T207A | Missense Mutation (SNP) | VAF 246/482 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV55724251; called by muse, varscan2
- KLHL2 | c.1601G>T p.R534I | Missense Mutation (SNP) | VAF 119/264 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99900332; called by muse, varscan2
- LAMC1 | c.3068G>A p.R1023Q | Missense Mutation (SNP) | VAF 344/505 reads (68%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.909); catalogued as rs765664758, COSV51133108; called by muse, mutect2, varscan2
- MARK1 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 272/924 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs369987878, COSV99081355; called by muse, varscan2
- METRNL | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 474/939 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1362802945, COSV60761494; called by muse, varscan2
- MFHAS1 | c.1585C>A p.H529N | Missense Mutation (SNP) | VAF 398/808 reads (49%) | SIFT tolerated (0.92); PolyPhen benign (0.297); catalogued as rs749143961; called by muse, mutect2, varscan2
- MUC16 | c.41144G>T p.S13715I | Missense Mutation (SNP) | VAF 239/457 reads (52%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.946); catalogued as rs1426142859, COSV66697259; called by muse, mutect2, varscan2
- MYH1 | c.5701C>T p.R1901C | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556246573, COSV56846472; called by muse, varscan2
- MYH8 | c.3430C>T p.R1144W | Missense Mutation (SNP) | VAF 224/482 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161189464, COSV67967763; called by muse, varscan2
- NEFM | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 267/564 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55330599; called by muse, varscan2
- NRBP2 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 256/524 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs1250308776; called by muse, varscan2
- NUTM1 | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 176/396 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV100148961; called by muse, varscan2
- OR5H6 | c.235C>A p.L79I (on ENST00000642105; = p.L63I on NM_001005479.2) | Missense Mutation (SNP) | VAF 156/292 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV101051799, COSV67351865; called by muse, varscan2
- PARP12 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 168/389 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs566167926, COSV54932292; called by muse, mutect2, varscan2
- PHRF1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 255/599 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs570207828; called by muse, mutect2, varscan2
- PLEKHG4 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 22/710 reads (3%) | catalogued as rs1339437364; called by muse, mutect2
- PRRG1 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 258/482 reads (54%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); catalogued as rs782480996; called by muse, mutect2, varscan2
- RAP1GAP2 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 178/367 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs144985620; called by muse, mutect2, varscan2
- REN | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 460/718 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1280455872, COSV65817433; called by muse, varscan2
- RFX6 | c.2743C>A p.P915T | Missense Mutation (SNP) | VAF 195/401 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100264425; called by muse, varscan2
- SEC14L2 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 190/405 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.172); catalogued as rs140915639; called by muse, mutect2, varscan2
- SGCD | c.475G>A p.G159R (on ENST00000435422 / NM_001128209.2; = p.G160R on NM_000337.5) | Missense Mutation (SNP) | VAF 132/270 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61910563; called by muse, varscan2
- SRRM2 | c.7522G>T p.E2508* | Nonsense Mutation (SNP) | VAF 335/753 reads (44%) | catalogued as COSV51941387; called by muse, mutect2, varscan2
- STARD13 | c.2218C>T p.R740W (on ENST00000336934 / NM_001243476.3; = p.R622W on NM_052851.3) | Missense Mutation (SNP) | VAF 281/785 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769306323; called by muse, mutect2, varscan2
- TBCB | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 300/626 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as rs1165184247; called by muse, varscan2
- TMPRSS11F | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 103/237 reads (43%) | catalogued as rs542655796, COSV62464715; called by muse, mutect2, varscan2
- TOR1A | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 170/346 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100693917; called by muse, mutect2, varscan2
- UTS2R | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 462/948 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs1420224601, COSV57453193; called by muse, varscan2
- WDR64 | c.1366C>T p.R456* | Nonsense Mutation (SNP) | VAF 231/772 reads (30%) | catalogued as rs775974984; called by muse, mutect2, varscan2
- ZNF419 | c.574A>C p.S192R | Missense Mutation (SNP) | VAF 214/446 reads (48%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.944); catalogued as COSV99692806; called by muse, mutect2, varscan2
- ZNF835 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 350/700 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV101606233, COSV73379348; called by muse, varscan2
- ABCB11 | c.702_703insG p.F235Vfs*36 | Frame Shift Ins (INS) | VAF 290/296 reads (98%) | called by mutect2, pindel*, varscan2
- ADAM29 | c.1151G>T p.C384F | Missense Mutation (SNP) | VAF 160/417 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ADAMTS16 | c.3648C>A p.C1216* | Nonsense Mutation (SNP) | VAF 208/418 reads (50%) | called by muse, mutect2, varscan2
- AGO1 | c.1071C>A p.N357K | Missense Mutation (SNP) | VAF 184/395 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ALKBH1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 229/439 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ARHGAP30 | c.2192C>G p.A731G | Missense Mutation (SNP) | VAF 585/875 reads (67%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CDCA2 | c.2311G>T p.G771* | Nonsense Mutation (SNP) | VAF 198/413 reads (48%) | called by muse, varscan2
- CEP295 | c.7670T>G p.L2557* | Nonsense Mutation (SNP) | VAF 23/268 reads (9%) | called by muse, mutect2
- CFAP94 | c.261G>T p.Q87H (on ENST00000320267 / NM_001352064.2; = p.Q93H on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CYP1B1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 844/844 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.269); called by muse, varscan2
- CYP27B1 | c.23C>A p.A8D | Missense Mutation (SNP) | VAF 224/480 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- DAG1 | c.2537C>A p.T846N | Missense Mutation (SNP) | VAF 354/743 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DHX9 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 239/765 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFCAB13 | c.538del p.I180Ffs*12 | Frame Shift Del (DEL) | VAF 124/290 reads (43%) | called by mutect2, pindel, varscan2
- ERC2 | c.1511C>A p.S504Y | Missense Mutation (SNP) | VAF 211/391 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EVC | c.2582G>T p.R861M | Missense Mutation (SNP) | VAF 228/436 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- FCHSD2 | c.1631A>G p.D544G | Missense Mutation (SNP) | VAF 358/716 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- FLII | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 213/438 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- FZD2 | c.1653_1654del p.F551Lfs*11 | Frame Shift Del (DEL) | VAF 190/527 reads (36%) | called by mutect2, pindel, varscan2
- GCN1 | c.617T>G p.F206C | Missense Mutation (SNP) | VAF 62/731 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- GFM2 | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 164/360 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- GOLGA2 | c.2352G>T p.E784D | Missense Mutation (SNP) | VAF 293/648 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- GOLGB1 | c.2954A>G p.K985R | Missense Mutation (SNP) | VAF 256/530 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HDLBP | c.3719A>C p.K1240T | Missense Mutation (SNP) | VAF 152/346 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- HLA-DMA | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 430/1002 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- IRAG2 | c.1974G>T p.Q658H | Missense Mutation (SNP) | VAF 150/324 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- KIAA1549 | c.3219G>A p.M1073I | Missense Mutation (SNP) | VAF 212/473 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KLRG1 | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 166/346 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- KRT74 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 340/705 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, varscan2
- LYST | c.7085C>G p.A2362G | Missense Mutation (SNP) | VAF 216/340 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- MAF | c.1044C>A p.Y348* | Nonsense Mutation (SNP) | VAF 320/678 reads (47%) | called by muse, mutect2, varscan2
- MANBA | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 168/314 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- MRNIP | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 218/501 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- MST1R | c.419A>T p.Q140L | Missense Mutation (SNP) | VAF 393/801 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PODXL2 | c.1346C>G p.T449R | Missense Mutation (SNP) | VAF 223/448 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- PRKDC | c.1808dup p.T605Nfs*7 | Frame Shift Ins (INS) | VAF 182/457 reads (40%) | called by mutect2, pindel, varscan2
- PSG11 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 80/300 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANGAP1 | c.1615dup p.L539Pfs*63 | Frame Shift Ins (INS) | VAF 249/582 reads (43%) | called by mutect2, pindel, varscan2
- RCAN1 | c.755dup p.S252Rfs*58 | Frame Shift Ins (INS) | VAF 165/452 reads (37%) | called by pindel, varscan2
- RGS12 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 373/720 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RREB1 | c.1169C>A p.A390E | Missense Mutation (SNP) | VAF 327/635 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SCP2 | c.1608A>T p.Q536H | Missense Mutation (SNP) | VAF 151/359 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SIGLEC8 | c.931G>C p.G311R | Missense Mutation (SNP) | VAF 277/600 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- SLC2A5 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 129/129 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX9 | c.970dup p.T324Nfs*254 | Frame Shift Ins (INS) | VAF 370/824 reads (45%) | called by mutect2, varscan2
- SOX9 | c.971delinsAA p.T324Kfs*254 | Frame Shift Ins (INS) | VAF 301/1224 reads (25%) | called by pindel, varscan2*
- SPAG17 | c.3028C>A p.Q1010K | Missense Mutation (SNP) | VAF 154/360 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNE2 | c.8143A>G p.T2715A | Missense Mutation (SNP) | VAF 210/451 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAP1 | c.1595T>G p.V532G | Missense Mutation (SNP) | VAF 337/729 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TCF7L2 | c.148_149del p.N50* | Frame Shift Del (DEL) | VAF 218/534 reads (41%) | called by mutect2, pindel, varscan2
- TET1 | c.3590del p.N1197Ifs*46 | Frame Shift Del (DEL) | VAF 195/489 reads (40%) | called by mutect2, pindel, varscan2
- TGM7 | c.1895A>T p.N632I | Missense Mutation (SNP) | VAF 261/555 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TMEM67 | c.2871del p.F957Lfs*3 | Frame Shift Del (DEL) | VAF 146/414 reads (35%) | called by mutect2, pindel, varscan2
- TNFRSF8 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 226/226 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TOMM22 | c.235A>C p.R79= | Splice Region (SNP) | VAF 189/352 reads (54%) | called by muse, mutect2, varscan2
- UBE2Z | c.967A>G p.K323E | Missense Mutation (SNP) | VAF 296/587 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ZNF516 | c.1421A>T p.Q474L | Missense Mutation (SNP) | VAF 300/300 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ZNF678 | c.431A>C p.K144T (on ENST00000343776 / NM_001367910.1; = p.K199T on NM_178549.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 421/645 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ANKRD13B | c.1461C>T p.R487= | Silent (SNP) | VAF 290/644 reads (45%) | catalogued as rs1422498489; called by muse, varscan2
- ARNT2 | c.90C>T p.T30= | Silent (SNP) | VAF 252/536 reads (47%) | catalogued as rs376706310; called by muse, varscan2
- BARHL2 | c.537C>T p.H179= | Silent (SNP) | VAF 241/522 reads (46%) | called by muse, varscan2
- BTBD17 | c.216G>A p.A72= | Silent (SNP) | VAF 394/810 reads (49%) | catalogued as rs766568463, COSV64729610; called by muse, varscan2
- C1orf53 | c.231A>G p.R77= | Silent (SNP) | VAF 692/1022 reads (68%) | called by muse, mutect2, varscan2
- CDCA2 | c.2310A>G p.L770= | Silent (SNP) | VAF 200/414 reads (48%) | called by muse, varscan2
- COL23A1 | c.54G>A p.A18= | Silent (SNP) | VAF 176/327 reads (54%) | catalogued as rs1262647936; called by muse, mutect2, varscan2
- COPZ1 | c.480G>T p.V160= | Silent (SNP) | VAF 217/458 reads (47%) | called by muse, mutect2, varscan2
- DHX34 | c.1968A>G p.K656= | Silent (SNP) | VAF 18/458 reads (4%) | called by muse, mutect2
- ECT2L | c.1464C>G p.G488= | Silent (SNP) | VAF 108/241 reads (45%) | called by muse, mutect2, varscan2
- ERN1 | c.2259C>T p.Y753= | Silent (SNP) | VAF 127/303 reads (42%) | called by muse, mutect2, varscan2
- F2RL3 | c.441C>T p.A147= | Silent (SNP) | VAF 426/877 reads (49%) | catalogued as rs368209439; called by muse, varscan2
- FARP2 | c.2913C>A p.A971= | Silent (SNP) | VAF 192/412 reads (47%) | called by muse, mutect2, varscan2
- FAT4 | c.720G>C p.V240= | Silent (SNP) | VAF 226/394 reads (57%) | called by muse, varscan2
- FRMD5 | c.1365C>T p.S455= | Silent (SNP) | VAF 330/660 reads (50%) | called by muse, mutect2, varscan2
- GLT6D1 | c.282G>A p.P94= | Silent (SNP) | VAF 160/326 reads (49%) | catalogued as rs765609739, COSV65627602; called by muse, mutect2, varscan2
- GRM7 | c.2472G>A p.T824= | Silent (SNP) | VAF 159/319 reads (50%) | catalogued as rs764120169, COSV63131834; called by muse, mutect2, varscan2
- HOXB9 | c.438C>A p.A146= | Silent (SNP) | VAF 384/783 reads (49%) | catalogued as COSV60817319; called by muse, varscan2
- ITGAV | c.1020A>G p.Q340= | Silent (SNP) | VAF 255/589 reads (43%) | called by muse, mutect2, varscan2
- JPH2 | c.405C>T p.N135= | Silent (SNP) | VAF 280/1018 reads (28%) | catalogued as rs140538587; ClinVar: uncertain significance; called by muse, varscan2
- KLRG1 | c.222C>T p.S74= | Silent (SNP) | VAF 167/347 reads (48%) | called by muse, mutect2, varscan2
- MMP3 | c.744G>C p.R248= | Silent (SNP) | VAF 244/472 reads (52%) | called by muse, mutect2, varscan2
- MTUS1 | c.2667G>A p.Q889= (on ENST00000262102 / NM_001363061.1; = p.Q55= on NM_020749.4) | Silent (SNP) | VAF 216/511 reads (42%) | called by muse, mutect2
- NACAD | c.1869C>A p.A623= | Silent (SNP) | VAF 465/992 reads (47%) | called by muse, mutect2, varscan2
- NLRP1 | c.2721G>A p.T907= | Silent (SNP) | VAF 200/440 reads (45%) | catalogued as rs200768469; ClinVar: likely benign; called by muse, varscan2
- PAX1 | c.333C>T p.N111= | Silent (SNP) | VAF 302/304 reads (99%) | catalogued as COSV101270260; called by muse, mutect2, varscan2
- PCDH17 | c.1698C>T p.N566= | Silent (SNP) | VAF 311/841 reads (37%) | catalogued as COSV64976965; called by muse, mutect2, varscan2
- PCDHB6 | c.1335C>T p.N445= | Silent (SNP) | VAF 314/672 reads (47%) | catalogued as rs1554277740, COSV50689781; called by muse, varscan2
- PCDHGC5 | c.675C>A p.T225= | Silent (SNP) | VAF 312/623 reads (50%) | called by muse, mutect2, varscan2
- PLS3 | c.555G>A p.K185= | Silent (SNP) | VAF 164/370 reads (44%) | catalogued as COSV56777183; called by muse, mutect2, varscan2
- SCN7A | c.282G>A p.A94= | Silent (SNP) | VAF 196/196 reads (100%) | catalogued as rs199938114; called by muse, mutect2, varscan2
- SERPINB9 | c.468A>G p.E156= | Silent (SNP) | VAF 214/500 reads (43%) | called by muse, mutect2, varscan2
- SLC12A5 | c.249C>A p.S83= (on ENST00000454036 / NM_001134771.2; = p.S60= on NM_020708.5) | Silent (SNP) | VAF 132/612 reads (22%) | called by muse, mutect2, varscan2
- SLC35G2 | c.978C>G p.V326= | Silent (SNP) | VAF 225/506 reads (44%) | catalogued as COSV67588749; called by muse, mutect2, varscan2
- TCF21 | c.159C>T p.R53= | Silent (SNP) | VAF 362/710 reads (51%) | called by muse, varscan2
- TCHHL1 | c.2712A>G p.Q904= | Silent (SNP) | VAF 275/450 reads (61%) | called by muse, mutect2, varscan2
- TGFB1I1 | c.924A>C p.P308= (on ENST00000394863 / NM_001042454.3; = p.P291= on NM_015927.4) | Silent (SNP) | VAF 231/541 reads (43%) | called by muse, mutect2, varscan2
- TRPV3 | c.873G>A p.S291= | Silent (SNP) | VAF 333/671 reads (50%) | catalogued as rs141405698; called by muse, mutect2, varscan2
- ZC3H11A | c.240C>T p.C80= | Silent (SNP) | VAF 175/594 reads (29%) | catalogued as rs774911667; called by muse, mutect2, varscan2
- ZC3H6 | c.513G>A p.L171= | Silent (SNP) | VAF 421/422 reads (100%) | called by muse, varscan2
- ZNF541 | c.2316G>A p.P772= | Silent (SNP) | VAF 284/618 reads (46%) | catalogued as COSV54543146; called by muse, mutect2, varscan2
- DLX5 | c.540+10G>A | Intron (SNP) | VAF 351/743 reads (47%) | called by muse, mutect2, varscan2
- GRAMD1B | c.374+913C>A | Intron (SNP) | VAF 245/491 reads (50%) | called by muse, mutect2, varscan2
- SERTM2 | c.-840C>A | 5'UTR (SNP) | VAF 168/371 reads (45%) | called by muse, mutect2, varscan2
- UNC13B | c.762-7105A>C | Intron (SNP) | VAF 144/308 reads (47%) | called by muse, varscan2
- VIPR2 | c.51+116G>C | Intron (SNP) | VAF 478/1016 reads (47%) | called by muse, mutect2, varscan2
